Somatic mutation profile of tumor specimen 0DGBAW from CCDI case PBBNKZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,615 days).
Specimen 0DGBAW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10d84b9-69ca-444d-b79c-f6ecdf6282c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGB8Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5487ad46-3d73-48bc-8c61-8d40d5de4da7

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBFOX1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 235/942 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150941982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHS | c.1653C>G p.P551= | Silent (SNP) | VAF 460/1246 reads (37%) | called by muse, mutect2, varscan2
